Gene-level copy-number profile of tumor specimen TCGA-AG-3582-01A from TCGA case TCGA-AG-3582, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 75.7 years (27,636 days).
Specimen TCGA-AG-3582-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.3674373f-1823-45cb-8537-0e3f7f14645b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3582-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/37e0030b-9507-4d29-a296-7b46bf30fcc7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 811; copy number 2: 11,663; copy number 3: 34,833; copy number 4: 7,241; copy number 5: 3,984; copy number 6: 576; copy number 7: 524; copy number 8: 59; copy number 9: 57; copy number 10: 60.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AG-3582-01): tumor purity 0.76, ploidy 3.1, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,884,250–15,022,958, 4 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 700 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:90,198,389–92,965,645, 36 genes, copy number 7 (within-gene range 5–7): AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7, AC103409.1, RN7SKP231, PRR13P7, MRPS16P1, RUNX1T1, AF181450.1, AC104339.1, AC022695.1, AC022695.2, AC022695.3, AC091096.1, AC104211.1, AC104211.3, FLJ46284, AC104211.2, AC117834.2, AC117834.1.
- chr16:30,357,102–30,923,269, 60 genes, copy number 10: TBC1D10B, AC106782.5, MYLPF, ZNF48, SEPTIN1, AC116348.4, ZNF771, SNORA80C, DCTPP1, SEPHS2, Y_RNA, Y_RNA, ITGAL, AC116348.3, AC116348.1, RNU7-61P, AC116348.2, MIR4518, ZNF768, AC002310.4, AC002310.5, ZNF747, AC002310.1, AC002310.3, ZNF764, ZNF688, AC002310.2, ZNF785, AC093249.2, AC093249.4, ZNF689, AC093249.3, AC093249.5, AC093249.1, PRR14, FBRS, RNU6-416P, AC093249.6, SRCAP, RNU6-1043P, AC106886.5, SNORA30, TMEM265, AC106886.2, PHKG2, CCDC189, RNF40, AC106886.4, ZNF629, Metazoa_SRP, AC106886.1, AC106886.3, BCL7C, MIR762HG, MIR4519, AC135048.2, MIR762, CTF1, CTF2P, FBXL19-AS1.
- chr20:30,278,906–52,670,578, 604 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 811. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
